Somatic mutation profile of tumor specimen BA2405D (aliquot aq-BA2405D) from BEATAML1.0 case 2354, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.5 years (16,246 days).
Specimen BA2405D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22365e19-7dcd-4691-9811-e0cc3afa2b54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2596D (Solid Tissue Normal), aliquot aq-BA2596D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/786b31fd-4bba-40cd-822c-526960ab2e2e

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 81/230 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ENTPD1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as rs1312380068, COSV100967585, COSV100967838; called by muse, mutect2, varscan2
- GRIN2B | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200727145, COSV74205564, COSV74206077; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, mutect2, varscan2
- MGAT5B | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56932722; called by muse, mutect2, varscan2
- UNKL | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100061706; called by muse, mutect2, varscan2
- CATSPERB | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5262A>C p.Q1754H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR6C2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZNF135 | c.919T>C p.F307L (on ENST00000313434 / NM_001289401.2; = p.F319L on NM_003436.4) | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARIH1 | c.255C>T p.G85= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs754910711, COSV65910196; called by mutect2, varscan2
- KIRREL1 | c.543C>T p.T181= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs1371881555; called by muse, mutect2, varscan2
- OR56A4 | c.363C>G p.L121= | Silent (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- RIN3 | c.501G>A p.T167= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs758738721, COSV53656183; called by muse, mutect2, varscan2
- LMBR1L | c.*16G>T | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
